CCDI case PBCHJB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/410590b1-f7ac-4497-9354-7046b0e03c81

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 15.7 years (5,718 days).

Biospecimens (3 samples)
- Sample 0DSHSW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSHT4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSHTE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
